FM case AD4603 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Small intestine.
https://portal.gdc.cancer.gov/cases/c4f0134d-cb41-4c0b-a96e-989b8c4e0027

Male, 66.9 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the duodenum. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Tumor.
